Gene-level copy-number profile of tumor specimen TCGA-D8-A1JL-01A from TCGA case TCGA-D8-A1JL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.5 years (26,484 days).
Specimen TCGA-D8-A1JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8f111081-c896-403e-b965-65d3e3a9ba62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a940cdce-89dc-45d2-b7f7-b3232f799766

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 8,945; copy number 2: 27,777; copy number 3: 16,036; copy number 4: 4,697; copy number 5: 1,125; copy number 6: 431; copy number 7: 543; copy number 8: 241.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JL-01A-11D-A13J-01): tumor purity 0.42, ploidy 2.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:35,962,195–36,487,548, 14 genes (within-gene range 0–1): OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,327 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,006,309–152,911,886, 200 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:33,277,025–34,694,174, 15 genes, copy number 5 (within-gene range 3–5): FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1.
- chr3:139,837,220–139,859,894, 2 genes, copy number 5: AC016933.1, TRMT112P5.
- chr6:13,214,056–14,646,638, 29 genes, copy number 7–8: RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P.
- chr7:70,972–17,680,659, 294 genes, copy number 5–7 (broad region; genes not listed).
- chr8:60,289,928–113,950,998, 810 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:44,712–19,790,401, 328 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr10:22,332,404–24,547,848, 30 genes, copy number 5: AL158211.4, AL158211.2, AL158211.3, SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P, ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2, AL512603.1, KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1.
- chr11:81,821,272–82,718,299, 1 gene, copy number 5 (within-gene range 3–5): MIR4300HG.
- chr11:82,603,529–82,970,584, 9 genes, copy number 5: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1.
- chr13:90,781,766–114,337,626, 352 genes, copy number 7 (broad region; genes not listed).
- chr15:23,225,876–24,090,821, 18 genes, copy number 6: AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:100,849,561–101,933,350, 42 genes, copy number 7 (within-gene range 3–7): AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr18:47,390–6,415,237, 128 genes, copy number 5–6 (broad region; genes not listed).
- chr18:35,241,030–37,232,172, 38 genes, copy number 5 (within-gene range 3–5): ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1.
- chr19:27,902,595–27,984,743, 1 gene, copy number 6 (within-gene range 3–6): AC005357.2.
- chr19:27,918,943–29,525,752, 30 genes, copy number 6 (within-gene range 3–6): AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1.

Autosomal genes at a single copy (total copy number 1): 7,646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
